Surgical pathology report (de-identified scan), TCGA case TCGA-HC-8265, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-8265-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Prostate, prostatectomy:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Prostate size: 5.0 x 3.9 x 3.5 cm, 38.3 gm.
3. Tumor quantitation: Approximately 40% of the prostate is involved, including both lobes.
4. Gleason grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 5/5.
- c. Total Gleason score: 8/10.
- d. Areas of pattern 4 are also identified.
5. Extraprostatic extension: Focally tumor extends outside the prostate gland in nerve tissue.
6. Seminal vesicle involvement: Tumor does not involve the seminal vesicle but is in the prostate tissue adjacent to the seminal vesicles.
7. Lymphovascular space invasion: Not diagnostically identified.
8. High grade PIN: Yes.

Surgical Margin Status:

1. Margins positive in the apical region, as well as both the right and left lobes.

Other:

1. pTNM stage: pT3a.

B. Pelvic lymph nodes, excision:

Total lymph nodes identified: 8

Total lymph nodes positive for metastatic carcinoma: 0 (0/8).

Electronic Signature: [REDACTED]

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Prostate cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Prostate
- B. Pelvic lymph nodes

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in two formalin-filled containers labeled with the patient's name

A. Container A is additionally labeled 'prostate' and contains a 38.3 gram, 5.0 x 3.9 x 3.5 cm prostate gland, received with attached bilateral adnexa. The adnexa has overall dimensions of 5.3 x 4.2 x 1.3 cm. The prostate is pink-tan and shaggy. It is inked as follows: right side blue and left side black. The base and apical margins are coned and serially sectioned. The remainder of the gland is serially sectioned from apex to base to reveal a 2.0 x 1.3 x 1.0 cm ill-defined tan-orange mass located within the left posterior quadrant and approaching to within 0.2 cm of the inked capsule. The remainder of the cut surface is pink-tan focally cystic and glistening with diffuse periurethral nodularity. No additional masses are identified. Representative sections are submitted in cassettes A1 through 18 labeled as follows: 1, right prostate/seminal vesicle junction; 2, left prostate/seminal vesicle junction; 3 and 4, apical margin, perpendicular; 5 and 6, base margin, perpendicular; 7 through 9, right anterior, apex to base; 10 through 12, right posterior, apex to base; 13 through 15, left anterior, apex to base; 16 through 18, left posterior, apex to base. Additionally, a yellow and green cassette are submitted for genomics research each labeled [REDACTED]

B. Container B is additionally labeled 'pelvic lymph nodes' and contains a 7.3 x 4.5 x 2.5 cm aggregate of yellow-tan fibrofatty soft tissue. On palpation,

six firm fatty possible lymph nodes are identified ranging from 0.4 up to 3.0 cm in greatest dimension. They are entirely submitted in cassettes B1 through 5 labeled as follows: B1, three whole possible lymph nodes; B2, one whole possible bisected lymph node; B3, one whole possible trisected lymph node; B4 and 5, one whole possible bisected lymph node.

Source: NCI Genomic Data Commons file 281bc356-671b-4261-b460-1fe1d06a421e (TCGA-HC-8265.7C2F8BB7-3FE0-459E-A885-6D7A97D753F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).